Somatic mutation profile of tumor specimen TCGA-24-0970-01B (aliquot TCGA-24-0970-01B-01W-0486-08) from TCGA case TCGA-24-0970, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.7 years (23,276 days).
Specimen TCGA-24-0970-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47575cc6-9dde-4fd7-aee9-c4677c478b4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-0970-10A (Blood Derived Normal), aliquot TCGA-24-0970-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac43ffde-035d-4b6f-8cc4-8f1919c0d681

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, Nonsense Mutation 3, In Frame Del 1, Frame Shift Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 199/436 reads (46%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CCDC151 | c.651G>T p.Q217H | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV62698126; called by muse, mutect2, varscan2
- CCDC39 | c.1966G>C p.E656Q | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV56485512; called by muse, mutect2, varscan2
- CEP97 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 34/97 reads (35%) | catalogued as rs1560019742, COSV59123192; called by muse, mutect2, varscan2
- CGNL1 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs771249830, COSV55569168; called by muse, mutect2, varscan2
- CYP4F12 | c.867C>G p.D289E | Missense Mutation (SNP) | VAF 140/779 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV61174142; called by muse, mutect2, varscan2
- DCT | c.1489A>G p.R497G | Missense Mutation (SNP) | VAF 30/666 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100986106; called by muse, mutect2
- EFCAB6 | c.2848C>T p.Q950* | Nonsense Mutation (SNP) | VAF 235/433 reads (54%) | catalogued as COSV53064756; called by muse, mutect2, varscan2
- ELAPOR2 | c.1103A>G p.Y368C (on ENST00000450689 / NM_001142749.3; = p.Y201C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370803630, COSV51887503, COSV51887766; called by muse, mutect2, varscan2
- EPHA7 | c.1696A>G p.T566A | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs77295523, COSV65183979; called by muse, mutect2, varscan2
- IL36B | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 146/465 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV52085934, COSV52086627; called by muse, mutect2, varscan2
- MUC17 | c.10538G>T p.G3513V | Missense Mutation (SNP) | VAF 112/334 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); catalogued as COSV60290649, COSV60301371; called by muse, mutect2, varscan2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 16/82 reads (20%) | catalogued as rs772439983; called by mutect2, varscan2
- NTN4 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as rs377286047; called by muse, mutect2, varscan2
- NXPE4 | c.1406T>C p.M469T (on ENST00000375478 / NM_001077639.2; = p.M185T on NM_017678.3) | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs201711836; called by muse, mutect2
- PHF19 | c.93C>G p.N31K | Missense Mutation (SNP) | VAF 9/271 reads (3%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100384267; called by muse, mutect2
- POLDIP2 | c.426C>G p.D142E | Missense Mutation (SNP) | VAF 140/283 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50228488; called by muse, mutect2, varscan2
- PXDNL | c.2096C>G p.S699C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs1490805673, COSV62486625, COSV62488306, COSV62488847; called by muse, mutect2
- SI | c.3715G>T p.V1239F | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV52281798; called by muse, mutect2, varscan2
- SMURF1 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 64/219 reads (29%) | catalogued as COSV62816200; called by mutect2, varscan2
- UTP14C | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as COSV73000690; called by muse, mutect2, varscan2
- ZNF208 | c.2087A>C p.E696A | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as COSV101236819; called by muse, varscan2
- AL592490.1 | c.1982_1990del p.I661_V663del | In Frame Del (DEL) | VAF 28/220 reads (13%) | called by mutect2, pindel
- ADAM22 | c.1050G>A p.S350= | Silent (SNP) | VAF 65/291 reads (22%) | catalogued as rs780863938, COSV55978525; called by muse, mutect2, varscan2
- FEM1A | c.1938C>G p.A646= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV54164037; called by muse, mutect2, varscan2
- KIAA2013 | c.1380G>A p.G460= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as rs755698565, COSV64860737; called by muse, mutect2, varscan2
- KRT72 | c.465C>A p.T155= | Silent (SNP) | VAF 69/270 reads (26%) | catalogued as rs775789816, COSV53374636; called by muse, mutect2, varscan2
- MYH11 | c.5886C>T p.D1962= | Silent (SNP) | VAF 347/684 reads (51%) | catalogued as rs140789717; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYRIP | c.2205G>A p.A735= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs201745391; called by muse, mutect2, varscan2
- PCDHAC1 | c.1809G>A p.A603= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as rs782369096, COSV53841202; called by muse, mutect2, varscan2
- SORCS3 | c.660C>T p.F220= | Silent (SNP) | VAF 313/903 reads (35%) | catalogued as COSV63812212; called by muse, mutect2, varscan2
- TMEM236 | c.993C>T p.Y331= | Silent (SNP) | VAF 69/275 reads (25%) | called by muse, mutect2, varscan2
- AF241726.1 | c.172-444689G>A | Intron (SNP) | VAF 193/374 reads (52%) | catalogued as COSV100655890; called by muse, mutect2, varscan2
